Somatic mutation profile of tumor specimen TCGA-AP-A0LV-01A (aliquot TCGA-AP-A0LV-01A-11W-A062-09) from TCGA case TCGA-AP-A0LV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 39.9 years (14,556 days).
Specimen TCGA-AP-A0LV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86639c7f-f7ef-4e5d-9336-2737db6ac5c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LV-10A (Blood Derived Normal), aliquot TCGA-AP-A0LV-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9d0fe48-6fdc-45ab-925d-00ccefbd0800

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 10, Frame Shift Del 2, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 26/83 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 120/334 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ACIN1 | c.1199C>G p.S400* | Nonsense Mutation (SNP) | VAF 45/117 reads (38%) | catalogued as COSV52977866; called by muse, mutect2, varscan2
- ANO2 | c.2752G>A p.V918I (on ENST00000356134 / NM_001278597.3; = p.V922I on NM_001278596.3) | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs781231821, COSV59008268; called by muse, mutect2, varscan2
- AP3M2 | c.815T>A p.I272N | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51529415; called by muse, mutect2, varscan2
- CDH10 | c.577G>T p.G193W | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52571617, COSV52586939, COSV52598182; called by muse, mutect2, varscan2
- DDC | c.1214T>C p.I405T | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV63565843; called by muse, mutect2
- DENND4A | c.3160G>A p.G1054R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.312); catalogued as COSV71266191; called by muse, mutect2, varscan2
- DNAH5 | c.8828G>A p.R2943H | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184758570, COSV54203923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCN | c.1157A>G p.H386R | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284212565, COSV55259245; called by muse, mutect2, varscan2
- NOMO3 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 168/228 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV53770011; called by muse, mutect2, varscan2
- SAMSN1 | c.208dup p.M70Nfs*14 | Frame Shift Ins (INS) | VAF 44/124 reads (35%) | catalogued as rs760167411; called by mutect2, varscan2
- SIRT3 | c.561C>A p.H187Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV61501242, COSV61501534; called by muse, mutect2, varscan2
- TGFB3 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs770911263, COSV53168787; called by muse, mutect2, varscan2
- ZNF827 | c.523del p.E175Rfs*39 | Frame Shift Del (DEL) | VAF 41/130 reads (32%) | catalogued as COSV65228567; called by mutect2, pindel, varscan2
- ERAP2 | c.1130_1142del p.F377Sfs*38 | Frame Shift Del (DEL) | VAF 39/133 reads (29%) | called by mutect2, pindel, varscan2
- CNR1 | c.708G>A p.A236= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs577054667, COSV62988555; called by muse, mutect2, varscan2
- FAM155B | c.1158C>T p.F386= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV52936691; called by muse, mutect2, varscan2
- KATNB1 | c.1380C>T p.N460= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1361186601, COSV65551120; called by muse, mutect2
- PNMA2 | c.6G>A p.A2= | Silent (SNP) | VAF 102/263 reads (39%) | catalogued as rs924910659, COSV72908551; called by muse, mutect2, varscan2
- SEZ6L | c.1128C>T p.D376= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs371203903; called by muse, mutect2, varscan2
- SH2B3 | c.1251G>A p.S417= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1455870142, COSV57984246; called by muse, mutect2, varscan2
- SLC9A4 | c.1824G>T p.L608= | Silent (SNP) | VAF 156/474 reads (33%) | catalogued as COSV54835462; called by muse, mutect2
- SLC9A8 | c.1038C>T p.L346= | Silent (SNP) | VAF 60/159 reads (38%) | catalogued as COSV64289200; called by muse, mutect2, varscan2
- STRA6 | c.1389C>T p.L463= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV60586882, COSV60587655; called by muse, mutect2, varscan2
- TLR9 | c.2304G>A p.A768= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs374571031; called by muse, mutect2, varscan2
- CAPS2 | c.1670-2732G>C | Intron (SNP) | VAF 88/222 reads (40%) | catalogued as COSV60826461; called by muse, mutect2, varscan2
